CTSP case CTSP-AD13 — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6ae555c0-6c58-4d03-9719-009cb96c339c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1958; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 51.1 years (18,674 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage II; Days to last follow up: 2,279 days (6.2 years); Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): Low Risk.

Biospecimens (1 sample)
- Sample DLBCL11310-sample: Sample type: Tumor; Tissue type: Tumor.
